Somatic mutation profile of tumor specimen TCGA-AB-2869-03A (aliquot TCGA-AB-2869-03A-01W-0732-08) from TCGA case TCGA-AB-2869, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,679 days).
Specimen TCGA-AB-2869-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd4d5403-c366-4f84-acde-1d09b6b07e1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2869-11A (Solid Tissue Normal), aliquot TCGA-AB-2869-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9995a5b4-4025-4102-80f5-2a87b7aae098

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 2890/2898 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55952754; called by mutect2, varscan2
- PGAP3 | c.261G>A p.V87= | Silent (SNP) | VAF 134/134 reads (100%) | catalogued as rs1351326784, COSV56131427; called by muse, mutect2, varscan2
- SLC27A5 | c.378G>A p.A126= | Silent (SNP) | VAF 76/620 reads (12%) | catalogued as rs373630138; ClinVar: uncertain significance; called by muse, varscan2
